Somatic mutation profile of tumor specimen TARGET-15-SJMPAL017978-09A.3 (aliquot TARGET-15-SJMPAL017978-09A.3-01D) from TARGET case TARGET-15-SJMPAL017978, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (730 days).
Specimen TARGET-15-SJMPAL017978-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6313fde4-0a01-46df-82ba-697cec5cf391.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL017978-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL017978-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebd566c2-21f3-4dfc-a847-fb276808982a

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASCL1 | c.237C>A p.H79Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.05); catalogued as rs1369888005; called by muse, varscan2
- FAM135B | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200240655; called by muse, mutect2, varscan2
- FAM186A | c.3875A>C p.N1292T | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1005894085, COSV59247760; called by muse, varscan2
- GLB1L2 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs147686340; called by muse, mutect2, varscan2
- JAK1 | c.2516G>T p.R839L | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61092796; called by muse, mutect2
- HTATSF1 | c.43C>A p.Q15K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2
- KIAA1109 | c.3778C>A p.H1260N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by mutect2, varscan2
- BMP2 | c.906C>T p.Y302= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs374065751; called by muse, mutect2, varscan2
- GOLGA8O | c.507C>T p.R169= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs778644601; called by muse, mutect2, varscan2
- MARCHF10 | c.1221C>T p.S407= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs777152212; called by muse, mutect2, varscan2
- MROH2A | c.2355C>T p.C785= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs770274993; called by muse, mutect2, varscan2
- TBC1D3B | c.1398G>C p.G466= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as rs1300595344; called by muse, mutect2
- HRC | c.*20C>T | 3'UTR (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
